CPTAC case C3L-01182 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ed4f6d0f-65af-41e2-8506-9c4e9d2a21f7

Demographics
Sex at birth: male; Race: white; Year of birth: 1998; Vital status: Alive; Country of birth: Russia.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 18.5 years (6,759 days); Year of diagnosis: 2017; Days to last known disease status: 255 days; Days to last follow up: 255 days; Calgb risk group: Intermediate/Normal.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 255.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 2.3; Cigarettes per day: 15; Tobacco smoking onset year: 2014; Exposure duration years: 8.

Biospecimens (5 samples)
- Samples C3L-01182-51, C3L-01182-52, C3L-01182-53 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-01182-58, C3L-01182-60 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 255 days; Method of sample procurement: Blood Draw; Diagnosis pathologically confirmed: Yes.
